Somatic mutation profile of tumor specimen 0DLJX2 from CCDI case PBBXUJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (547 days).
Specimen 0DLJX2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2785d631-083a-496e-a328-c790e4da1d1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLJWL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73b5055e-c946-4769-8f67-d53e0a517708

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 3, Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RNF225 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 22/570 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52191433; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 42/1136 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ADGRD1 | c.*44C>G | 3'UTR (SNP) | VAF 132/254 reads (52%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.*3870C>G | 3'UTR (SNP) | VAF 10/177 reads (6%) | called by muse, mutect2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 7/59 reads (12%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- PPP2R3B | c.1085+77C>T | Intron (SNP) | VAF 89/294 reads (30%) | catalogued as rs773241230; called by muse, mutect2, varscan2
